Somatic mutation profile of tumor specimen TCGA-DJ-A2QC-01A (aliquot TCGA-DJ-A2QC-01A-11D-A18F-08) from TCGA case TCGA-DJ-A2QC, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 70.3 years (25,690 days).
Specimen TCGA-DJ-A2QC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe8aae2c-62bf-492f-9103-93272eae3188.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2QC-10A (Blood Derived Normal), aliquot TCGA-DJ-A2QC-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33ce6acb-1c6c-4c77-960c-1207f514f5ba

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AL645922.1 | c.443A>C p.Y148S | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV54962796; called by muse, mutect2, varscan2
- CDCA2 | c.1053T>G p.Y351* | Nonsense Mutation (SNP) | VAF 5/58 reads (9%) | catalogued as COSV57948825; called by muse, mutect2
- KCNK18 | c.858T>G p.I286M | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.099); catalogued as COSV57973450; called by muse, mutect2
- NANOS3 | c.487C>T p.P163S (on ENST00000397555; = p.P182S on NM_001098622.2) | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV59250067; called by muse, mutect2
- SLC6A19 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV58674918; called by muse, mutect2
- NSL1 | c.168C>T p.F56= | Silent (SNP) | VAF 14/240 reads (6%) | catalogued as rs776037762, COSV65325035; called by muse, mutect2
- SLC12A9 | c.492C>T p.Y164= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs570239035, COSV51937448; called by muse, mutect2, varscan2
- ZNF251 | c.828C>T p.L276= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV52959500; called by muse, mutect2
